Gene-level copy-number profile of tumor specimen TCGA-D6-8569-01A from TCGA case TCGA-D6-8569, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,212 days).
Specimen TCGA-D6-8569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5e0e0536-b9f0-4e91-a31e-134ca5aea094.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-8569-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/238ed933-fb69-4109-8219-f8d0bee0f442

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 12,141; copy number 3: 22,858; copy number 4: 21,307; copy number 5: 1,665; copy number 6: 47; copy number 7: 1,794.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-8569-01A-11D-2390-01): tumor purity 0.43, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,794 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:95,916,726–176,114,537, 1,303 genes, copy number 7 (broad region; genes not listed).
- chr3:176,814,155–198,222,513, 478 genes, copy number 7 (broad region; genes not listed).
- chr9:110,024,881–110,579,880, 6 genes, copy number 7 (within-gene range 4–7): AL158823.1, C9orf152, TXN, TXNDC8, SVEP1, RNU6-1039P.
- chr9:137,867,925–138,203,325, 7 genes, copy number 7: AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
